Somatic mutation profile of tumor specimen TCGA-HU-A4GJ-01A (aliquot TCGA-HU-A4GJ-01A-11D-A25D-08) from TCGA case TCGA-HU-A4GJ, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 60.4 years (22,079 days).
Specimen TCGA-HU-A4GJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0fbcb991-b341-4a1e-b4c1-d2cf0d3447a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HU-A4GJ-10A (Blood Derived Normal), aliquot TCGA-HU-A4GJ-10A-01D-A25E-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/96f8d755-9e91-47c6-9433-4213ba1bc8d8

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent.
By variant classification: Silent 2, Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAM221A | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 8/159 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.107); catalogued as COSV61387139, COSV99049320; called by muse, mutect2
- PASD1 | c.1752G>T p.Q584H | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100949017, COSV64856831; called by muse, mutect2
- FCHO1 | c.1095G>A p.P365= | Silent (SNP) | VAF 7/171 reads (4%) | catalogued as rs1337997630, COSV99405751; called by muse, mutect2
- PCDHA9 | c.1752G>A p.S584= | Silent (SNP) | VAF 8/194 reads (4%) | catalogued as rs782099893, COSV100968930; called by muse, mutect2
